Surgical pathology report (de-identified scan), TCGA case TCGA-78-8660, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-8660-01A (Primary Tumor).

HISTORY

1): (R) lower lobe apical segment resection. 2): Hilar LN.

MACROSCOPIC

Two specimens received:

1: The specimen is labelled 'apex of (R) lower lobe' and consists of a segment of lung measuring 140 x 60 x 40 mm when inflated. A diathermied resection margin is identified covering an area of 70 x up to 45 mm. In this area a bronchial resection margin, together with a stapled vascular resection margin, is identified. Extending from this region is a stapled parenchymal resection margin, 100 mm in length. The pleural surface is red and glistening with areas of black carbon pigmentation. There is a linear area of pleural scarring measuring 30 mm opposite the stapled resection margin. Sectioning reveals a tumour nodule, 33 x 25 x up to 25 mm, beneath this area of scarring. The tumour has a well-defined outline and a homogenous, solid, cream cut surface. It is located subpleurally and possibly invades the pleura. It is at least 20 mm from where the stapled resection margin has been removed, 40 mm from the bronchial resection margin, and up to 10 mm from the diathermied resection margin. The adjacent lung parenchyma shows patchy carbon pigmentation but no focal lesions or emphysematous change. [1A, bronchial and vascular resection margin; 1B-D, tumour with overlying pleura; 1E, parenchymal resection margin; 1F, normal lung].

2: The specimen is labelled 'hilar lymph node' and consists of six fragments of grey tissue, 15 x 10 x 5 mm in aggregate. [BIT, 2A].

MICROSCOPY

1: Sections show an extensively necrotic, moderately to poorly differentiated adenocarcinoma which abuts and focally invades into the overlying pleura. Vascular and lymphatic invasion are also identified but no perineural invasion is seen. The inked surgical resection margin and bronchial resection margin are well clear of malignancy. Distant lung parenchyma shows mild emphysema.

2: Sections show extensive replacement of the lymph node fragments by focally necrotic metastatic adenocarcinoma.

SUMMARY

Right lower lobe apical segmentectomy and hilar lymph node sampling:
Moderately to poorly differentiated adenocarcinoma, 33 mm in diameter.
Pleural, vascular and lymphatic invasion present.
Metastases in hilar lymph nodes.
Pathological stage T2 N1.

Source: NCI Genomic Data Commons file b4d2e336-8ed9-4449-8ced-332cac163691 (TCGA-78-8660.2C53D65A-D792-41BC-A6C3-CD2D079A5386.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).